Somatic mutation profile of tumor specimen 0DGJ83 from CCDI case PBBTLR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.5 years (4,583 days).
Specimen 0DGJ83: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 307e90e9-3b45-40f7-b9e0-7b6f90986b74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGJ64 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec1568c9-fe36-4f80-8811-d891b11ed55a

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, 3'UTR 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 187/281 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 126/309 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 210/315 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 42/292 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; called by muse, mutect2
- FCRL6 | c.604+8C>T | Splice Region (SNP) | VAF 30/262 reads (11%) | catalogued as rs778703492, COSV58940310; called by muse, mutect2
- GPR179 | c.3830C>T p.S1277L (on ENST00000621958; = p.S1276L on NM_001004334.4) | Missense Mutation (SNP) | VAF 234/507 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1187854272; called by muse, mutect2, varscan2
- H2BC3 | c.169T>G p.S57A | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV63551093; called by muse, mutect2, varscan2
- LMNTD1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs367548196, COSV99279401; called by muse, mutect2, varscan2
- MCOLN1 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 184/500 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99900796; called by mutect2, varscan2
- NEO1 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.754); catalogued as rs1240753781, COSV56067272; called by muse, varscan2
- PLA2G6 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 27/641 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as rs1162944680; called by muse, mutect2
- PLG | c.1813C>A p.H605N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100369174; called by mutect2, varscan2
- RNPC3 | c.1406C>G p.A469G | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166554367, COSV63716972; called by muse, mutect2, varscan2
- SOHLH1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 195/757 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as rs528068735, COSV53681805; called by muse, mutect2, varscan2
- TDRD15 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs796716084; called by muse, mutect2, varscan2
- USH1C | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs754263265; called by muse, mutect2, varscan2
- CTPS2 | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- EFCAB13 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FABP9 | c.337A>C p.K113Q | Missense Mutation (SNP) | VAF 23/477 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); called by muse, mutect2
- KIFC3 | c.1949T>C p.L650P | Missense Mutation (SNP) | VAF 298/741 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STX6 | c.572del p.G191Efs*28 | Frame Shift Del (DEL) | VAF 140/519 reads (27%) | called by mutect2, pindel, varscan2
- TRPC3 | c.1033G>T p.G345C (on ENST00000379645 / NM_001366479.2; = p.G272C on NM_003305.2) | Missense Mutation (SNP) | VAF 190/476 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZFYVE26 | c.6830A>G p.H2277R | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ABHD18 | c.1008T>C p.S336= (on ENST00000398965 / NM_001039717.2; = p.S243= on NM_025097.2 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 273/499 reads (55%) | catalogued as rs1175813571; called by muse, mutect2, varscan2
- NLRP11 | c.2538C>T p.S846= | Silent (SNP) | VAF 100/262 reads (38%) | catalogued as rs114044008; called by muse, mutect2, varscan2
- PNPLA7 | c.1914C>T p.Y638= | Silent (SNP) | VAF 159/624 reads (25%) | catalogued as rs532244437; called by muse, mutect2, varscan2
- SLC25A29 | c.873C>T p.A291= (on ENST00000359232 / NM_001039355.3; = p.A225= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/287 reads (4%) | called by muse, mutect2
- ZBBX | c.879C>T p.C293= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs766281414; called by muse, mutect2, varscan2
- ZMYND8 | c.528C>T p.P176= (on ENST00000311275 / NM_001363741.2; = p.P196= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 175/236 reads (74%) | catalogued as rs961436262, COSV53693046; called by muse, mutect2, varscan2
- CDC20B | c.*4C>T | 3'UTR (SNP) | VAF 103/333 reads (31%) | called by muse, mutect2, varscan2
- TRIML1 | c.*22C>G | 3'UTR (SNP) | VAF 47/459 reads (10%) | called by muse, mutect2, varscan2
